Somatic mutation profile of tumor specimen TCGA-41-4097-01A (aliquot TCGA-41-4097-01A-01D-1353-08) from TCGA case TCGA-41-4097, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.3 years (23,107 days).
Specimen TCGA-41-4097-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b18fa80c-de7e-41ac-a3a6-bcf4a8131a9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-41-4097-10A (Blood Derived Normal), aliquot TCGA-41-4097-10A-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33952b8e-74d7-483c-b84b-4b71a9cc586c

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 5, Frame Shift Del 1, 5'Flank 1, Nonsense Mutation 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.705C>G p.Y235* | Nonsense Mutation (SNP) | VAF 44/103 reads (43%) | catalogued as rs769048538, CM086301, CM153406, COSV62215531; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTRT2 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV65760165; called by muse, varscan2
- ANO2 | c.2278C>G p.P760A (on ENST00000356134 / NM_001278597.3; = p.P764A on NM_001278596.3) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59037720; called by muse, mutect2
- APOO | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV64871077; called by muse, mutect2, varscan2
- ARHGEF10 | c.2447C>T p.P816L (on ENST00000398564; = p.P791L on NM_014629.4) | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV50668807; called by muse, mutect2, varscan2
- CNDP2 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV60841154; called by muse, mutect2, varscan2
- CPNE7 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs145109453; called by muse, mutect2, varscan2
- CXorf65 | c.426G>A p.P142= | Splice Region (SNP) | VAF 18/63 reads (29%) | catalogued as rs1055386186, COSV52149811; called by muse, mutect2, varscan2
- DHX30 | c.649G>A p.A217T (on ENST00000445061 / NM_138615.3; = p.A178T on NM_014966.3) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138418233; called by muse, mutect2, varscan2
- FBN2 | c.7496C>A p.P2499Q | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52536917; called by muse, mutect2, varscan2
- KDM4D | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58635928; called by muse, mutect2, varscan2
- KMT2C | c.2470G>C p.G824R | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51484944; called by muse, varscan2
- LAMP3 | c.143T>C p.I48T | Missense Mutation (SNP) | VAF 102/352 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55613481; called by muse, mutect2, varscan2
- LRRIQ1 | c.2381C>G p.T794S | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs1235980587, COSV67836522; called by muse, mutect2, varscan2
- MAGEB3 | c.343A>G p.T115A | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV64397599; called by muse, mutect2, varscan2
- OR10S1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs141270826; called by muse, mutect2, varscan2
- PDC | c.376A>C p.T126P | Missense Mutation (SNP) | VAF 69/325 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV60854668; called by muse, mutect2, varscan2
- PTEN | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64288643, COSV64296223, COSV64303479; called by muse, mutect2, varscan2
- SIGLEC5 | c.667A>T p.T223S | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.028); catalogued as COSV55782605; called by muse, mutect2, varscan2
- SLC27A2 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 61/220 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.26); catalogued as rs141444028; called by muse, mutect2, varscan2
- SLC4A1 | c.2074C>G p.P692A | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV52262352; called by muse, mutect2, varscan2
- ZFHX4 | c.1305G>A p.M435I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs529333807, COSV51487417; called by muse, mutect2, varscan2
- ZMIZ1 | c.2579A>C p.E860A | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as COSV57901788; called by muse, mutect2, varscan2
- ZNF460 | c.1035C>G p.F345L | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64415639; called by muse, mutect2, varscan2
- ANKRD17 | c.7066del p.A2356Hfs*23 | Frame Shift Del (DEL) | VAF 43/240 reads (18%) | called by mutect2, pindel, varscan2
- APOB | c.12051C>T p.D4017= | Silent (SNP) | VAF 31/124 reads (25%) | catalogued as rs12713501; called by muse, mutect2, varscan2
- DLGAP4 | c.105G>A p.S35= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as rs371870979; called by muse, mutect2, varscan2
- MAGEB6B | c.777C>T p.G259= | Silent (SNP) | VAF 39/192 reads (20%) | catalogued as rs767666470; called by muse, mutect2, varscan2
- OR13C4 | c.909A>G p.V303= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV52928040; called by muse, mutect2, varscan2
- RGS22 | c.2379A>G p.E793= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV62662019, COSV62666073; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73820961 G>A | 3'Flank (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503714 del TC | 5'Flank (DEL) | VAF 28/131 reads (21%) | called by pindel, varscan2
